Gene-level copy-number profile of tumor specimen C3N-00302-02 from CPTAC case C3N-00302, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.0 years (21,532 days).
Specimen C3N-00302-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f133361-e580-41f5-a860-fee9406eddb3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00302-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/3ffe031b-8751-4aee-94a1-2d84dc35413d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 29; copy number 2: 16,160; copy number 3: 6,514; copy number 4: 29,311; copy number 5: 3,459; copy number 6: 1,123; copy number 7: 1,580; copy number 8: 99; copy number 9: 7; copy number 10: 36; copy number 13: 1; copy number 16: 53; copy number 20: 16.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,614,419–68,670,652, 4 genes (within-gene range 0–2): AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr13:23,765,934–23,766,104, 1 gene (within-gene range 0–2): MTCO3P2.
- chr14:18,702,281–18,712,643, 2 genes: CR383656.2, NF1P10.
- chr19:42,839,368–43,171,515, 8 genes (within-gene range 0–2): PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 113 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:71,581,721–71,628,558, 1 gene, copy number 9 (within-gene range 4–9): AC097634.3.
- chr3:71,675,414–71,827,471, 4 genes, copy number 9: EIF4E3, GPR27, PROK2, RN7SL271P.
- chr3:72,006,774–72,006,975, 1 gene, copy number 9: UBE2Q2P9.
- chr3:73,382,431–73,624,941, 1 gene, copy number 13 (within-gene range 3–13): PDZRN3.
- chr8:41,490,396–42,541,926, 33 genes, copy number 9–20 (within-gene range 4–20): GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1.
- chr19:39,812,972–41,261,766, 73 genes, copy number 10–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
